Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A0CH, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A0CH-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3
carcinoma, infiltrating duct, NOS 8509/3
Site: breast, NOS C50.9 lw 9/3/11

SPECIMEN

- A. Sentinel node left breast
- B. Left breast
- C. Left sentinel node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Left breast cancer

FROZEN SECTION DIAGNOSIS

- A. Benign on frozen section.
- C. Benign on frozen section.

GROSS DESCRIPTION

A. Received fresh in a container labeled "A. sentinel node

left breast" is a portion of soft to rubbery tissue, 2.6 x 2 x 0.7 cm. Externally much of the specimen is fatty. On cut surface, there is some tan-pink lymph node tissue, with prominent fat replacement. The specimen is entirely submitted for frozen section in three blocks.

B. Received fresh in a container labeled "left breast" is a 33 x 16 x 3.5 cm mastectomy specimen, partially surfaced by a 20 x 11 cm tan-pink wrinkled skin ellipse, with a 1.6 cm in diameter everted nipple. There is no gross lesion on the skin surface. There is an arrow indicating superior. The deep aspect of the specimen is inked and the specimen is serially sectioned, revealing a 3.3 x 3.3 x 2 cm tan-white firm indurated mass which is 1.3 cm from the deep margin. The mass is located centrally but slightly laterally, with the closest margin the aforementioned deep margin, with the tumor not grossly near a margin. The specimen outside the mass lesion consists of yellow adipose tissue with interspersed tan-white tissue, without additional focal lesion. No lymph nodes are identified with the breast. RS-10.

GROSS DESCRIPTION

BLOCK SUMMARY: B1, B2 - entire nipple, and skin; B3 - deep margin deep to tumor; B4-B6 - tumor (sections do not include margin); B7 - inner upper quadrant; B8 - inner lower quadrant; B9 - outer lower quadrant; B10 - outer upper quadrant.

C. Received fresh in a container labeled "left sentinel node" is a portion of soft to rubbery tan-yellow tissue, 2 x 1.5 x 0.7 cm. On cut surface, the specimen is predominantly fatty, with some identifiable tan-pink lymph node tissue. It is entirely submitted for frozen section in two blocks.

[page 2 of 3]
MICROSCOPIC DESCRIPTION

A,C. The lymph nodes are negative for malignancy. In addition to examining serial H&E stained sections, immunostains with antibodies to keratin (AE1/AE3) are examined, without specific staining, supporting the interpretation that the lymph nodes are negative for malignancy.

B. The following template summarizes the findings in this part:

Invasive carcinoma: Present in the mass lesion in the breast in part

B

Histologic type: Invasive ductal carcinoma
Histologic grade:
Overall grade: 1
Architectural score: 2
Nuclear score: 2
Mitotic score: 1

MICROSCOPIC DESCRIPTION

Greatest dimension (pT): 3.3 cm (pT2)
Specimen margins: Negative for tumor
Vessel invasion: Not identified
Calcification: Present focally
Nipple: Negative for tumor
Invasion of skin or chest wall: Not identified

Ductal carcinoma in situ: Present very focally, with the vast majority of the carcinoma in this specimen invasive carcinoma.

Histologic pattern: Cribriform
Nuclear grade: 1-2
Central necrosis: Absent
Specimen margins: Negative
Calcification: Not identified within DCIS

Description of non-tumorous breast: Fibrocystic changes.

Prognostic markers: Previously performed on a prior specimen at an outside institution.

4x3, 14x2, 15x3, 20x5

[page 3 of 3]
DIAGNOSIS

A,C. Lymph nodes, left sentinel, excisions -
Negative for malignancy.

B. Breast, left, excision -
Invasive ductal carcinoma (see microscopic description).
Skin, nipple, and margins negative for malignancy.

M.D. (Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file 0211303d-8c37-4f22-916b-c8dfe4ed439a (TCGA-A7-A0CH.F70DA7E5-2AB3-487F-8B2C-72EEE91E58E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).